Somatic mutation profile of tumor specimen MP2PRT-PAPIBM-TMP1-A (aliquot MP2PRT-PAPIBM-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPIBM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,581 days).
Specimen MP2PRT-PAPIBM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 211c6987-9786-42b7-8394-ecb72f155aa5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIBM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIBM-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/024dd7e5-1d81-4bc0-9215-a361ed9f8b62

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTHFD1L | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs536864868; called by muse, mutect2, varscan2
- RIC3 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV58305621; called by muse, mutect2, varscan2
- SPAG17 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs139343615; called by muse, mutect2, varscan2
- ADAM29 | c.2160A>T p.K720N | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- EVX1 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 17/537 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2
- KRTAP13-3 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 117/566 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FGFR2 | c.1545C>T p.A515= | Silent (SNP) | VAF 64/352 reads (18%) | catalogued as rs778789088, COSV60640726; called by muse, mutect2, varscan2
- PILRB | c.33C>T p.L11= | Silent (SNP) | VAF 148/342 reads (43%) | catalogued as rs1475236708; called by muse, mutect2, varscan2
- SNED1 | c.225C>T p.N75= | Silent (SNP) | VAF 80/200 reads (40%) | catalogued as rs753706591, COSV60021455; called by muse, mutect2, varscan2
